Gene-level copy-number profile of tumor specimen TCGA-AN-A04A-01A from TCGA case TCGA-AN-A04A, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 36.8 years (13,445 days).
Specimen TCGA-AN-A04A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.928be25e-9343-4042-a5c0-851465def55b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A04A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a4da6b5-1fe3-42f1-b387-892b504e0d3c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 734; copy number 2: 19,469; copy number 3: 25,108; copy number 4: 9,779; copy number 5: 1,999; copy number 6: 1,068; copy number 7: 863; copy number 8: 546; copy number 9: 25; copy number 10: 169; copy number 11: 31; copy number 52: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A04A-01A-21D-A036-01): tumor purity 0.56, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,654 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:22,569,566–22,675,493, 3 genes, copy number 8: HDGFL1, AL033539.1, AL033539.2.
- chr6:24,544,104–25,057,073, 20 genes, copy number 7 (within-gene range 6–7): KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2, MTCO2P33, PPIAP29, AL160400.1, ASS1P1, RN7SL334P, AL133268.3, AL133268.2.
- chr6:25,061,796–25,181,745, 4 genes, copy number 7: AL133268.4, AL133268.1, AL590084.3, AL590084.1.
- chr6:25,726,063–25,930,726, 10 genes, copy number 7: H2AC1, H2BC1, H2BC2P, H2AC2P, SLC17A4, SLC17A1, SLC17A3, H2AC3P, H2BP5, SLC17A2.
- chr8:96,239,398–145,066,685, 773 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr10:30,434,021–31,529,814, 20 genes, copy number 52: MAP3K8, HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2, AL590068.3, LYZL2, SVIL2P, LINC02644, ZNF438, AL359532.1, DDX10P1, AL359546.1, LINC02664, ZEB1-AS1, RNA5SP309, ZEB1, SPTLC1P1, AL117340.1.
- chr15:76,336,773–77,820,900, 25 genes, copy number 9 (within-gene range 6–9): ISL2, AC027243.1, AC027243.2, SCAPER, AC090751.1, MIR3713, RN7SKP217, RCN2, RN7SL278P, KRT8P23, PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1, HMG20A, AC090984.1, AC046168.1, AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2.
- chr15:92,762,757–101,933,350, 193 genes, copy number 8–10 (broad region; genes not listed).
- chr17:48,646,923–50,768,730, 119 genes, copy number 8–11 (within-gene range 2–11) (broad region; genes not listed).
- chr17:51,177,425–69,553,865, 452 genes, copy number 7–10 (within-gene range 2–10) (broad region; genes not listed).
- chr18:10,454,635–10,489,949, 1 gene, copy number 7: APCDD1.
- chr18:61,592,375–63,644,256, 34 genes, copy number 7–10 (within-gene range 3–10): AC105094.2, AC105094.1, LINC01544, RNF152, PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4.

Autosomal genes at a single copy (total copy number 1): 734. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
